CCDI case PBBNMG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/2fe580ae-8822-4d37-8149-25e6014f0883

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Ovary; Age at diagnosis: 17.9 years (6,524 days).

Biospecimens (2 samples)
- Sample 0DDEQA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDEQD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
